Somatic mutation profile of tumor specimen BA3001D (aliquot aq-BA3001D) from BEATAML1.0 case 2344, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.6 years (18,833 days).
Specimen BA3001D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0079fd90-9e82-4af7-9b30-2ef014b5dac2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2585D (Solid Tissue Normal), aliquot aq-BA2585D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e4dfeb9-ea9a-4891-8ac2-7cb29fc423ce

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, Frame Shift Del 1, 5'UTR 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTR5 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780725473, COSV54760677, COSV54760819; called by muse, mutect2
- CLCN4 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.856); catalogued as COSV66466160; called by muse, mutect2, varscan2
- FAT1 | c.4994C>T p.P1665L | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761417017; called by muse, mutect2, varscan2
- KMT2C | c.5716C>T p.R1906* | Nonsense Mutation (SNP) | VAF 47/117 reads (40%) | catalogued as rs763438739, COSV51279719, COSV51462477; called by muse, mutect2, varscan2
- SMC1A | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781817340, COSV59128385; called by muse, mutect2, varscan2
- TAF1L | c.4186C>T p.R1396C | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs535208015, COSV54265096; called by mutect2, varscan2
- THBS1 | c.2989G>A p.A997T | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368416842, COSV52950997, COSV52954108; called by muse, varscan2
- USH2A | c.10451G>A p.R3484Q | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs771999994, COSV56367008; called by muse, mutect2, varscan2
- BEX1 | c.20G>T p.R7L | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- DLX1 | c.620C>A p.A207D | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.028); called by muse, mutect2
- MAP1A | c.1819G>A p.D607N | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPEF2 | c.402T>G p.D134E | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TMEM144 | c.928G>A p.G310S | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.634); called by muse, varscan2
- WWC1 | c.1663del p.L555Sfs*18 | Frame Shift Del (DEL) | VAF 34/92 reads (37%) | called by mutect2, pindel, varscan2
- FZD10 | c.474C>T p.P158= | Silent (SNP) | VAF 7/75 reads (9%) | called by muse, mutect2
- HSF4 | c.357C>A p.R119= | Silent (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- NPAP1 | c.783G>C p.A261= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV61504567; called by muse, mutect2, varscan2
- CCDC188 | c.733-19T>C | Intron (SNP) | VAF 6/10 reads (60%) | catalogued as rs73150876; called by mutect2, varscan2
- PEG10 | c.-243C>T | 5'UTR (SNP) | VAF 6/69 reads (9%) | catalogued as COSV56018866; called by muse, mutect2, varscan2
